Surgical pathology report (de-identified scan), TCGA case TCGA-G4-6309, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G4-6309-01A (Primary Tumor).

[page 1 of 3]
SPECIMENS:

- A. SIGMOID COLON
- B. PROXIMAL DONUT
- C. DISTAL DONUT

SPECIMEN(S):

- A. SIGMOID COLON
- B. PROXIMAL DONUT
- C. DISTAL DONUT

GROSS DESCRIPTION:**A. SIGMOID COLON**

Received fresh for tissue procurement and labeled with the patient's name and "sigmoid colon" is a closed, unoriented segment of colon measuring 13 cm in length with a diameter of 5 cm. There is an area of stricture measuring 1.2 cm, which is 4.5 cm from the nearest surgical margin. This region is inked black. The colon is opened and there is a fungating exophytic polypoid mass with serpentine border measuring 3.9 cm in length with a diameter of 3.0 cm. It appears to invade through the muscularis propria. It is located 3.5 cm from the nearest surgical margin and approximately 7.5 cm from the distant margin. The mucosa, extending from the mass to its nearest surgical margin, has a granular appearance. Sections of mass and normal appearing mucosa are submitted for tissue procurement. Normal mucosa is submitted for RNA study. Representative sections are submitted as follows:

- A1: margin closest to mass
- A2: margin distal to mass
- A3-A4: sections of mass and deep margin
- A5-A6: granular mucosa
- A7: normal-appearing mucosa
- A8-A9: six possible lymph nodes each distal to mass
- A10-A11: four possible lymph nodes each in proximity to mass
- A12: two bisected lymph nodes adjacent to mass

B. PROXIMAL DONUT

Received in formalin and labeled with the patient's name and "proximal donut" is a donut of pink-tan mucosal tissue measuring 3.2 x 2.4 x 0.6 cm. There is a blue suture throughout the specimen. It is bisected and the mucosa is unremarkable. Representative section is submitted in block B1.

C. DISTAL DONUT

Received in formalin and labeled with the patient's name and "distal donut" is a donut of pink-tan mucosal tissue measuring 2.2 x 1.7 x 0.5 cm. The mucosal surface has pinpoint areas of hemorrhage. There are surgical staple present. Representative section is submitted in block C1.

DIAGNOSIS:**A. COLON, SIGMOID, SEGMENTAL RESECTION:**

- INVASIVE ADENOCARCINOMA, MODERATELY AND POORLY DIFFERENTIATED, SEE SYNOPSIS.
- 3.9 CM IN GREATEST DIMENSION.
- 3.0 X 1.2 CM IN ADDITIONAL DIMENSIONS.
- INVADING INTO THE SUBSEROA.
- THE PROXIMAL, DISTAL, AND RADIAL MARGINS ARE NEGATIVE FOR TUMOR.
- THE TUMOR IS 3.5 CM FROM THE PROXIMAL MARGIN (CLOSEST MARGIN).
- SUSPICIOUS FOR ANGIOLYMPHATIC INVASION.
- NO PERINEURAL INVASION IDENTIFIED.
- ASSOCIATED WITH A TUBULAR ADENOMA.
- METASTATIC CARCINOMA TO TWO OF TWENTY FOUR LYMPH NODES (2/24), WITH EXTRANODAL EXTENSION.

B. COLON, PROXIMAL MARGIN, SEGMENTAL RESECTION:

- NO MALIGNANCY IDENTIFIED.

C. COLON, DISTAL MARGIN, SEGMENTAL RESECTION:

- NO MALIGNANCY IDENTIFIED.

[page 2 of 3]
COMMENT: THE RESULTS OF EXPRESSION OF MISMATCH REPAIR PROTEINS WILL BE ISSUED AS AN ADDENDUM.

SYNOPTIC REPORT - COLON & RECTUM

Specimens Involved

Specimens: A: SIGMOID COLON

Specimen Type: Sigmoidectomy

Tumor Site: Sigmoid colon

Tumor Configuration: Exophytic (polypoid)

Tumor size: 3.9cm Additional dimensions 3cm x 1.2cm

WHO Classification

Adenocarcinoma 8140/3

Histologic Grade: G3: Poorly differentiated

Extent of Invasion: Subserosa

Margins: Margin(s) uninvolved by invasive carcinoma (Proximal, Distal, Radial)

Distance of invasive carcinoma from closest margin: 3.5cm

Venous/Lymphatic Invasion: Absent

Perineural Invasion: Absent

Additional Pathologic Findings: Adenoma

Extent of Resection: R0: Complete resection with grossly and microscopically negative margins

Lymph Nodes: Positive 2 / 24

Extranodal extension: Present

Implants: Absent

Pathological Staging (pTNM): pT 3 N 1 M X

CLINICAL HISTORY:

None provided

PRE-OPERATIVE DIAGNOSIS:

Colon ca

ADDENDUM:

ANALYSIS OF MISMATCH REPAIR PROTEIN EXPRESSION

SUMMARY OF IMMUNOHISTOCHEMISTRY/SPECIAL STAINS

Material: Block A4

Population: Tumor Cells

Stain/Marker:Result: Comment:

MLH1 Positive

MSH2 Positive

MSH6 Positive

PMS2 Negative

The interpretation of the above immunohistochemistry stain or stains is guided by published results in the medical literature, provided package information from the manufacturer and by internal review of staining performance and assay validation within the [REDACTED] of the. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These tests were developed and their performance characteristic determined by the [REDACTED] at. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

INTERPRETATION: No expression of PMS2 identified.

[page 3 of 3]
[REDACTED]

Expression of MLH1, MSH2, MSH6, and PMS2 in the tumor was evaluated by immunohistochemistry. Peritumoral lymphocytes and normal glands serve as internal positive controls expressing MLH1, MSH2, MSH6, and PMS2.

Testing for Microsatellite Instability has been ordered. The results will be issued in a separate report.

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file cc8f2d68-02f0-4ab8-9883-f65ed203d9af (TCGA-G4-6309.AE3C7A6C-7DEC-49C3-BCC7-454A49C1201D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).